Somatic mutation profile of tumor specimen 0DIMWX from CCDI case PBBVGX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 14.7 years (5,366 days).
Specimen 0DIMWX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 315cc375-49a0-40d1-9293-7f53ba05c398.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64113f37-da24-4935-a2a8-27cf4be380c8

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2H5 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 178/444 reads (40%) | catalogued as rs121434364, CM041784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDELR2 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779857337; called by muse, mutect2, varscan2
- UNC13A | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 262/556 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764119582, COSV53189928; called by muse, varscan2
- CNTN2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- FAM171B | c.201A>T p.T67= | Silent (SNP) | VAF 228/536 reads (43%) | called by muse, varscan2
- NRXN2 | c.1113C>T p.N371= | Silent (SNP) | VAF 221/490 reads (45%) | catalogued as rs201527514; called by muse, mutect2, varscan2
- TRIM42 | c.573C>T p.C191= | Silent (SNP) | VAF 216/494 reads (44%) | catalogued as rs143917166; called by muse, mutect2, varscan2
- SSH2 | c.107+32785A>G | Intron (SNP) | VAF 94/230 reads (41%) | catalogued as rs981762148; called by muse, mutect2, varscan2
